Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9F2, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9F2-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Melanoma, spindle cell ^{NO.}
8772/3

Site Maxal tract C69.4

Op 2/16/14

Enucleation of the right eye.

Macroscopy:

The eyeball measures 28X20 mm and the posterior optic nerve segment 7 mm. At the section, it presents a black tumor measuring 13 mm main line. The piece has been fixed and included entirely.

*See path discrepancy form for
epithelioid and spindle cell ratio.*

Microscopy

The specimens observed present a cell proliferation with the histological features of a melanoma. This tumor is mainly composed of fusiform cells (97%) which present moderate nuclear atypias and a large cytoplasm frequently loaded with melanin. The mitotic index is low (three mitoses per 10 high power field).

The tumor size is 13 mm main line.

The lesion invades the ciliary body . The sclera is free.

The optic nerve on its entire course as well as its cut end and the meningeal sheath are free of tumor.

Conclusion:

Uveal melanoma composed of fusiform cells (97%).

Epithelioid cells: <3%

Tumor size: 13 mm.

Tumor extension of the ciliary body.

The sclera is free.

No extrascleral extension.

Optic nerve in its entire course, cut end of the optic nerve and meningeal sheaths free of tumor.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	<3% epithelioid cells 97% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% spindle cells 1-30% epithelioid cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file a85fed87-e1ae-4877-acb9-f2566d3b1ea4 (TCGA-V4-A9F2.9CD19F68-3AF3-402C-9FBF-D103337991D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).